Somatic mutation profile of tumor specimen TARGET-20-PASLYX-04A (aliquot TARGET-20-PASLYX-04A-01D) from TARGET case TARGET-20-PASLYX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,392 days).
Specimen TARGET-20-PASLYX-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc0b5a18-dba5-4e0f-8d71-57fe45b56955.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLYX-14A (Bone Marrow Normal), aliquot TARGET-20-PASLYX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7401f6f-c9ea-4e96-a3d2-f87c372f23f0

The open-access MAF lists 20 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 6, Silent 3, Intron 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBFA2T2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as rs529726824; called by mutect2, varscan2
- FLNB | c.3784G>A p.G1262R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139932035; called by muse, mutect2, varscan2
- KDM8 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141947860; called by mutect2, varscan2
- NLRP3 | c.1576T>A p.F526I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1201864980; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- RAD50 | c.3929A>G p.N1310S | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as rs753468016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WT1 | c.1094_1103dup p.A370Cfs*6 | Frame Shift Ins (INS) | VAF 34/106 reads (32%) | catalogued as COSV60075684, COSV60080453; called by mutect2, varscan2
- FAM9A | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- WT1 | c.746_753del p.F249* | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- BSN | c.3744G>A p.T1248= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs774678530, COSV56526379; called by muse, mutect2, varscan2
- ERF | c.282G>A p.L94= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as rs762831348; called by muse, mutect2, varscan2
- NPM1 | c.45G>A p.Q15= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ATXN1 | c.*5228_*5231delinsA | 3'UTR (DEL) | VAF 13/146 reads (9%) | catalogued as rs1313826922; called by pindel, varscan2*
- CELSR2 | c.6013+34A>G | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs1267684937; called by muse, mutect2, varscan2
- HDAC4 | c.*853C>G | 3'UTR (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- MAML3 | c.*2005_*2008dup | 3'UTR (INS) | VAF 17/138 reads (12%) | catalogued as rs1553949966; called by mutect2, varscan2
- PPM1F | c.*1064_*1065del | 3'UTR (DEL) | VAF 29/159 reads (18%) | called by pindel, varscan2
- SERPINA10 | c.-51+174G>A | Intron (SNP) | VAF 17/118 reads (14%) | catalogued as rs754459691; called by muse, mutect2, varscan2
- SIAE | c.*1076_*1078dup | 3'UTR (INS) | VAF 23/178 reads (13%) | called by mutect2, pindel, varscan2
- ZNF814 | c.*2312C>T | 3'UTR (SNP) | VAF 32/170 reads (19%) | catalogued as rs767188519; called by muse, mutect2, varscan2
